Somatic mutation profile of tumor specimen MMRF_2012_1_BM_CD138pos (aliquot MMRF_2012_1_BM_CD138pos_T1_KHS5U_L08092) from MMRF case MMRF_2012, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.5 years (22,827 days).
Specimen MMRF_2012_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4a1b925-d8fe-44c8-b4cb-44bca811f8b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2012_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2012_1_PB_Whole_C2_KHS5U_L08093; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00de279a-ceb9-45c1-9e8b-1e049361aa47

The open-access MAF lists 186 somatic variants for this specimen: 81 protein-altering or splice-affecting, 17 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, 3'UTR 57, Intron 19, Silent 17, Nonsense Mutation 6, 5'UTR 6, RNA 3, Splice Site 3, In Frame Del 2, Frame Shift Del 2, 3'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF2AK4 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 84/257 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587777106, CM140018; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLT4 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 205/311 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451816005, CM032232, CM1311596, COSV56098538; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CES3 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs370193889; called by muse, mutect2, varscan2
- CHD2 | c.4909del p.R1637Efs*177 | Frame Shift Del (DEL) | VAF 35/151 reads (23%) | catalogued as CM153777; called by mutect2, pindel, varscan2
- DCSTAMP | c.902T>G p.L301R | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52576825, COSV99886075; called by muse, mutect2, varscan2
- EYS | c.2645T>C p.F882S | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs773607543, COSV65481324; called by muse, mutect2, varscan2
- GNAI1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as rs758691743, COSV63523172; called by muse, mutect2, varscan2
- H1-3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.444); catalogued as rs774839714; called by muse, mutect2, varscan2
- IFNA5 | c.554T>G p.L185* | Nonsense Mutation (SNP) | VAF 4/82 reads (5%) | catalogued as rs1563845073; called by muse, mutect2
- IGHV2-70 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs373471089; called by muse, varscan2
- IGHV3-30 | c.343T>A p.C115S | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1403552040; called by muse, varscan2
- IGHV4-34 | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1064189; called by muse, mutect2
- IGLV3-1 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs372924773; called by muse, varscan2
- IGLV3-1 | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369274122; called by muse, varscan2
- IGLV4-3 | c.194A>C p.Y65S | Missense Mutation (SNP) | VAF 70/133 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as rs563438042; called by muse, mutect2, varscan2
- IRX1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs755172641, COSV57360839; called by muse, mutect2, varscan2
- KCNT1 | c.2945C>T p.T982M (on ENST00000488444; = p.T1001M on NM_020822.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs372775166; called by muse, mutect2, varscan2
- KIAA0319 | c.1568A>G p.N523S | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1457473564; called by muse, mutect2, varscan2
- MYO7B | c.5179G>A p.E1727K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs778564583; called by muse, mutect2, varscan2
- NR2E1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 223/599 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472108317, COSV64561768; called by muse, mutect2, varscan2
- NR3C2 | c.201A>T p.K67N | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV100678573; called by muse, mutect2, varscan2
- NTSR1 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV65139010; called by muse, mutect2, varscan2
- OR4K2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 107/533 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV53851775; called by muse, mutect2, varscan2
- PBDC1 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.764); catalogued as COSV64895917; called by muse, mutect2, varscan2
- PCDH15 | c.1268C>A p.P423H | Missense Mutation (SNP) | VAF 108/260 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100217882; called by muse, mutect2
- PLCD1 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as rs1335830144; called by muse, mutect2, varscan2
- RPL10A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 76/352 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV57689403; called by muse, mutect2, varscan2
- SCN3A | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs745450559, COSV51815216; called by muse, mutect2, varscan2
- SFRP4 | c.792-4del | Splice Region (DEL) | VAF 20/48 reads (42%) | catalogued as rs745763643; called by mutect2, varscan2
- SHROOM4 | c.1784A>G p.E595G | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782587151; called by muse, mutect2, varscan2
- ST8SIA1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs1344859630; called by muse, mutect2, varscan2
- TLR8 | c.2752G>T p.E918* (on ENST00000218032 / NM_138636.5; = p.E936* on NM_016610.4) | Nonsense Mutation (SNP) | VAF 45/67 reads (67%) | catalogued as COSV54318201, COSV54319409; called by muse, mutect2, varscan2
- TMPRSS11F | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100678459; called by muse, mutect2, varscan2
- URB1 | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs776461902; called by muse, mutect2, varscan2
- ADAMTSL2 | c.746A>T p.K249M | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL3 | c.368G>C p.S123T (on ENST00000506720 / NM_001322402.2; = p.S55T on NM_015236.6) | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ANKRD13A | c.229+2T>A p.X77_splice | Splice Site (SNP) | VAF 77/143 reads (54%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 106/138 reads (77%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASTN1 | c.3679G>T p.D1227Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- CFAP46 | c.5056C>T p.L1686F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- CHD9 | c.5621G>A p.R1874K | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CIART | c.1148_1150del p.L383_N384delinsH | In Frame Del (DEL) | VAF 98/195 reads (50%) | called by mutect2, pindel, varscan2
- DDX27 | c.518C>G p.T173S | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEFB125 | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- DNAH5 | c.8344C>T p.L2782F | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DNAH8 | c.8657C>A p.A2886E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- FAM135A | c.1193T>G p.L398* (on ENST00000370479 / NM_001351599.1; = p.L381* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 63/276 reads (23%) | called by muse, mutect2, varscan2
- FAM169A | c.1157A>T p.E386V | Missense Mutation (SNP) | VAF 149/239 reads (62%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAT4 | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 122/273 reads (45%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1919T>C p.I640T | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GUCY1B1 | c.1721C>A p.S574Y | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- HBA1 | c.420dup p.Y141Ifs*37 | Frame Shift Ins (INS) | VAF 151/426 reads (35%) | called by mutect2, pindel, varscan2
- HMCN1 | c.3923C>A p.T1308K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- IGHV1-69D | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.227); called by muse, varscan2
- IQGAP1 | c.3838A>T p.N1280Y | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- IRAG2 | c.2894del p.N965Mfs*33 (on ENST00000636465; = p.N10Mfs*33 on NM_006152.4 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- MAX | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 134/148 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- METTL2A | c.916+1G>T p.X306_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | called by muse, varscan2
- MUC16 | c.27317C>T p.T9106I | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NAA35 | c.837G>T p.L279F | Missense Mutation (SNP) | VAF 114/189 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, varscan2
- NUP160 | c.2544C>G p.S848R | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- OR4D10 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PDZD7 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKDREJ | c.4784T>C p.I1595T | Missense Mutation (SNP) | VAF 101/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNKP | c.1545C>A p.Y515* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- PSME1 | c.74_77del p.X25_splice | Splice Site (DEL) | VAF 54/159 reads (34%) | called by pindel, varscan2
- PTCHD3 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- RNF122 | c.101_103del p.P34del | In Frame Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel
- ROBO2 | c.2675A>C p.N892T | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- RRP36 | c.84C>A p.D28E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.043); called by muse, mutect2
- STARD8 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 120/175 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STYXL2 | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBX18 | c.34A>C p.M12L | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCF20 | c.791A>G p.Y264C | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TMEM132C | c.287A>T p.N96I | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TPSG1 | c.664T>G p.S222A | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UBE3A | c.465A>T p.R155S | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- UNC13C | c.4168G>C p.G1390R | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XKR4 | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZFR | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF469 | c.6547G>A p.A2183T (on ENST00000437464; = p.A2211T on NM_001367624.2) | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ANKRD34A | c.1284C>T p.L428= | Silent (SNP) | VAF 84/187 reads (45%) | called by muse, mutect2, varscan2
- ANKS6 | c.801C>T p.D267= | Silent (SNP) | VAF 59/108 reads (55%) | catalogued as rs763514014; called by muse, mutect2, varscan2
- C4BPA | c.1726C>T p.L576= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- COPE | c.264T>A p.A88= | Silent (SNP) | VAF 77/374 reads (21%) | called by muse, mutect2, varscan2
- ENPP7 | c.1275T>A p.P425= | Silent (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- GAD2 | c.1143G>T p.L381= | Silent (SNP) | VAF 69/167 reads (41%) | catalogued as COSV99393956; called by muse, mutect2, varscan2
- HNF1B | c.852C>T p.H284= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs149581999; ClinVar: benign; called by muse, mutect2, varscan2
- IGHV1-69D | c.291A>T p.T97= | Silent (SNP) | VAF 61/262 reads (23%) | called by muse, varscan2
- IGLV3-1 | c.6A>T p.A2= | Silent (SNP) | VAF 80/170 reads (47%) | catalogued as rs1219066661; called by muse, varscan2
- INPPL1 | c.2823G>A p.T941= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs906764223; called by muse, mutect2, varscan2
- KIRREL3 | c.1635T>G p.G545= | Silent (SNP) | VAF 55/106 reads (52%) | called by muse, mutect2, varscan2
- OR10G8 | c.837G>A p.T279= | Silent (SNP) | VAF 200/370 reads (54%) | catalogued as rs138666219; called by muse, mutect2, varscan2
- PIEZO2 | c.7737A>T p.T2579= | Silent (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- RASGRF2 | c.2031G>A p.V677= | Silent (SNP) | VAF 49/139 reads (35%) | called by muse, mutect2, varscan2
- SMOX | c.243C>T p.I81= | Silent (SNP) | VAF 158/253 reads (62%) | called by muse, mutect2, varscan2
- SPATA32 | c.585C>T p.A195= | Silent (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- TBC1D1 | c.2031T>C p.D677= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- AC139491.1 | n.704A>G | RNA (SNP) | VAF 92/188 reads (49%) | called by mutect2, varscan2
- AFF2 | c.*634C>A | 3'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- ALDH1A1 | c.747+41A>G | Intron (SNP) | VAF 44/189 reads (23%) | called by muse, mutect2, varscan2
- APOOL | c.*5484T>G | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- ARHGAP33 | c.*4C>G | 3'UTR (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- ASIC4 | c.1344+33G>A | Intron (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- ASPN | c.*918A>T | 3'UTR (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- BRWD3 | c.*843T>C | 3'UTR (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- BX664718.2 | n.840G>T | RNA (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- CACNA1E | c.*1980C>T | 3'UTR (SNP) | VAF 25/63 reads (40%) | catalogued as rs565081801; called by muse, mutect2, varscan2
- CD82 | c.*812A>T | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- CD99L2 | c.*305C>T | 3'UTR (SNP) | VAF 7/66 reads (11%) | catalogued as rs991015529; called by muse, mutect2, varscan2
- CDK19 | c.-26C>A | 5'UTR (SNP) | VAF 113/329 reads (34%) | catalogued as COSV100098517; called by muse, mutect2, varscan2
- CLIP1 | c.3966+233G>A | Intron (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- CYB561A3 | c.393+95T>A | Intron (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- DCBLD2 | c.*291_*292del | 3'UTR (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- DNAJC17 | c.*1647G>A | 3'UTR (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- DOCK5 | c.*2413C>T | 3'UTR (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2, varscan2
- DSEL | c.*1036A>C | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- EIF5A2 | c.*3781C>T | 3'UTR (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- ERAL1 | c.489+31A>C | Intron (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- ERBIN | c.*1696C>T | 3'UTR (SNP) | VAF 31/116 reads (27%) | catalogued as rs1051431975; called by muse, mutect2, varscan2
- ETFBKMT | c.*3294C>G | 3'UTR (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- EXOC6B | c.*2731A>C | 3'UTR (SNP) | VAF 55/124 reads (44%) | called by muse, mutect2, varscan2
- FAM135B | c.*1108G>A | 3'UTR (SNP) | VAF 5/106 reads (5%) | catalogued as rs1457965349; called by muse, mutect2
- FLRT2 | c.*4149T>A | 3'UTR (SNP) | VAF 34/56 reads (61%) | called by muse, mutect2, varscan2
- FO681492.1 | c.*1046_*1047insA | 3'UTR (INS) | VAF 55/225 reads (24%) | catalogued as rs1163990656; called by mutect2, pindel, varscan2
- GLUD1 | c.*549A>C | 3'UTR (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2
- GRIA2 | c.-205G>T | 5'UTR (SNP) | VAF 45/89 reads (51%) | called by muse, mutect2, varscan2
- HECTD2 | c.*416C>A | 3'UTR (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- HFE | c.*2353T>G | 3'UTR (SNP) | VAF 62/109 reads (57%) | called by muse, mutect2, varscan2
- HNRNPL | c.*3A>T | 3'UTR (SNP) | VAF 48/115 reads (42%) | called by muse, mutect2, varscan2
- HOXA13 | c.*487C>A | 3'UTR (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- HTR2C | c.-80+25566A>G | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- IKZF2 | c.*1639A>G | 3'UTR (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- IL13RA2 | c.*49A>G | 3'UTR (SNP) | VAF 38/337 reads (11%) | called by muse, mutect2, varscan2
- IL16 | chr15:81313181 ins G | 3'Flank (INS) | VAF 53/202 reads (26%) | called by mutect2, pindel, varscan2
- IL4R | c.70+863G>C | Intron (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- IL4R | c.71-849C>T | Intron (SNP) | VAF 94/205 reads (46%) | catalogued as rs745323859; called by muse, mutect2, varscan2
- IVD | c.153+285T>A | Intron (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- KCNT2 | c.*1572del | 3'UTR (DEL) | VAF 49/134 reads (37%) | called by mutect2, pindel, varscan2
- LPP | c.1240+2227G>A | Intron (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- LYST | c.*789_*791del | 3'UTR (DEL) | VAF 5/62 reads (8%) | called by mutect2, pindel
- MEGF9 | c.*3454T>A | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- MICALL2 | c.2638+13G>A | Intron (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- MTURN | c.*3324C>T | 3'UTR (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- NAMPT | c.*1431G>A | 3'UTR (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- NDOR1 | c.*220C>T | 3'UTR (SNP) | VAF 50/154 reads (32%) | called by muse, mutect2
- NECTIN3 | c.*1343A>G | 3'UTR (SNP) | VAF 53/115 reads (46%) | called by muse, mutect2, varscan2
- NKX2-4 | c.-84C>G | 5'UTR (SNP) | VAF 14/54 reads (26%) | catalogued as rs562281925; called by muse, mutect2, varscan2
- NRK | c.490-79G>C | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- ONECUT2 | c.*8739T>G | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2
- PARD6B | c.*1828G>T | 3'UTR (SNP) | VAF 39/130 reads (30%) | catalogued as rs1159363904; called by muse, mutect2, varscan2
- PCOLCE2 | c.*377T>G | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- PDE10A | c.*3517A>G | 3'UTR (SNP) | VAF 112/164 reads (68%) | catalogued as rs1429834902; called by muse, mutect2, varscan2
- PITRM1 | c.2646-693G>C | Intron (SNP) | VAF 185/359 reads (52%) | called by muse, mutect2, varscan2
- PLEKHJ1 | chr19:2230350 del CGCCCTGGCGC | 3'Flank (DEL) | VAF 30/145 reads (21%) | called by mutect2, pindel, varscan2
- PPP1R12A | c.*1274C>T | 3'UTR (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- PRRG3 | c.*4654T>A | 3'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- PTGDR2 | c.*941A>G | 3'UTR (SNP) | VAF 81/187 reads (43%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+4855C>T | Intron (SNP) | VAF 38/83 reads (46%) | catalogued as rs867589933; called by muse, mutect2, varscan2
- RAB6A | c.-245C>T | 5'UTR (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- RAB6D | c.*1347_*1348del | 3'UTR (DEL) | VAF 98/221 reads (44%) | called by mutect2, varscan2
- RABGAP1L | c.2212-11852T>A | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs1360817956; called by muse, mutect2, varscan2
- RN7SL860P | chr19:22601372 G>C | 5'Flank (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- RNF115 | c.*627dup | 3'UTR (INS) | VAF 8/18 reads (44%) | catalogued as rs1285642256; called by mutect2, varscan2
- RSPO4 | c.*538_*549del | 3'UTR (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- RTN4IP1 | c.-401G>A | 5'UTR (SNP) | VAF 50/127 reads (39%) | called by muse, mutect2, varscan2
- SAMHD1 | c.1642-722C>T | Intron (SNP) | VAF 55/165 reads (33%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.*816C>G | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- SIX1 | c.*2548G>A | 3'UTR (SNP) | VAF 27/30 reads (90%) | catalogued as rs1040754267; called by muse, mutect2, varscan2
- SLC25A21 | c.-11G>A | 5'UTR (SNP) | VAF 61/136 reads (45%) | catalogued as rs533287855; called by muse, mutect2, varscan2
- SLC37A3 | c.*1370G>A | 3'UTR (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- SLC6A14 | c.*1922G>T | 3'UTR (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- SSBP2 | c.*2202G>T | 3'UTR (SNP) | VAF 36/92 reads (39%) | called by muse, mutect2, varscan2
- STKLD1 | c.584-11T>C | Intron (SNP) | VAF 63/244 reads (26%) | called by muse, mutect2, varscan2
- STPG2 | c.*2568C>A | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- TMEFF2 | c.*264T>C | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- TUSC1 | c.*1168G>C | 3'UTR (SNP) | VAF 105/171 reads (61%) | called by muse, mutect2, varscan2
- UBE2L6 | c.*517A>G | 3'UTR (SNP) | VAF 55/104 reads (53%) | called by muse, mutect2, varscan2
- WWC2 | c.*47G>A | 3'UTR (SNP) | VAF 100/234 reads (43%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1656G>A | 3'UTR (SNP) | VAF 60/124 reads (48%) | catalogued as rs1176286002; called by muse, mutect2, varscan2
- ZBTB34 | c.*1412T>C | 3'UTR (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- ZDHHC23 | c.1041-591A>C | Intron (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- ZNF157 | c.*358T>A | 3'UTR (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- ZNF202 | c.*444C>T | 3'UTR (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- ZNF74 | c.121-860T>A | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- ZNF971P | n.450G>T | RNA (SNP) | VAF 6/16 reads (38%) | catalogued as rs1376545680; called by muse, mutect2, varscan2
